Somatic mutation profile of tumor specimen ALCH-B396-TTP1-A (aliquot ALCH-B396-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B396, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.7 years (20,361 days).
Specimen ALCH-B396-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efe79f7f-c118-4815-849c-e337a1188ef2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B396-NB1-A (Blood Derived Normal), aliquot ALCH-B396-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47750112-a9be-49b5-98b1-960949ed0750

The open-access MAF lists 738 somatic variants for this specimen: 505 protein-altering or splice-affecting, 151 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 441, Silent 151, Nonsense Mutation 43, Intron 36, RNA 20, 3'UTR 11, Splice Site 11, 5'UTR 6, 5'Flank 5, Frame Shift Del 5, 3'Flank 4, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A2 | c.2693G>T p.G898V | Missense Mutation (SNP) | VAF 48/567 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs794727669, COSV99798199; ClinVar: likely pathogenic; called by muse, mutect2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 44/254 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RNASEH1 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 30/523 reads (6%) | catalogued as rs373442996, CM156927; ClinVar: pathogenic; called by muse, mutect2
- A1CF | c.76C>G p.R26G | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV51055694; called by muse, mutect2
- ABCB11 | c.3647G>C p.G1216A | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769192036, COSV99792403; ClinVar: uncertain significance; called by muse, varscan2
- ABCB5 | c.2150T>A p.I717K (on ENST00000404938 / NM_001163941.2; = p.I272K on NM_178559.6) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV51724358; called by muse, mutect2
- ACTN2 | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 48/479 reads (10%) | catalogued as COSV63976962, COSV63978975; called by muse, mutect2, varscan2
- ADAM22 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV55981739; called by muse, mutect2
- ADGRG4 | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV99794687; called by muse, mutect2
- ADH1B | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 36/488 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV59294987; called by muse, mutect2
- ADH6 | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52957312; called by muse, mutect2, varscan2
- ADRA2B | c.478G>T p.G160W | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV69787567; called by muse, mutect2
- AFDN | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1323103308, COSV60053429; called by muse, mutect2, varscan2
- AGER | c.1162C>A p.L388M | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV61249074; called by muse, mutect2
- ARHGEF12 | c.3940C>T p.P1314S | Missense Mutation (SNP) | VAF 13/282 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV63104053; called by muse, mutect2
- ARMCX2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs782307127, COSV100168205; called by muse, mutect2
- ARSI | c.751C>G p.R251G | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV60816605; called by muse, mutect2, varscan2
- BNC1 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100597054; called by muse, mutect2
- BRIP1 | c.2995A>G p.R999G | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.287); catalogued as CD084049; called by muse, mutect2, varscan2
- BTBD9 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1315146575; called by muse, mutect2
- C16orf78 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.122); catalogued as COSV54557814, COSV54559004; called by muse, varscan2
- CAAP1 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100445345; called by muse, mutect2
- CACNA1F | c.3762G>T p.W1254C | Missense Mutation (SNP) | VAF 22/499 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1470900683; called by muse, mutect2
- CACNB2 | c.296C>T p.A99V (on ENST00000324631 / NM_201596.3; = p.A44V on NM_000724.4) | Missense Mutation (SNP) | VAF 57/661 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.767); catalogued as COSV56620035, COSV56624648; called by muse, mutect2
- CAMK2A | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100652128; called by muse, mutect2
- CD300A | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV60410298, COSV60411164; called by muse, mutect2
- CDC42BPB | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV100775737; called by muse, mutect2
- CHM | c.1157G>T p.C386F | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100752934; called by muse, mutect2
- CLDN17 | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99729077; called by muse, mutect2, varscan2
- CLPTM1 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.09); catalogued as COSV61611745; called by muse, mutect2, varscan2
- CMTR2 | c.255G>C p.W85C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57602369; called by muse, mutect2, varscan2
- CNTN6 | c.2600C>A p.T867K | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as COSV63182302; called by muse, mutect2, varscan2
- COL24A1 | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV100994218; called by muse, mutect2
- CTNND2 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.879); catalogued as rs1252461309, COSV58915383; called by muse, mutect2
- CWC22 | c.1961T>C p.I654T | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs759768641; called by muse, mutect2, varscan2
- CYRIA | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 26/333 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100838469; called by muse, mutect2
- DCAF4L2 | c.952C>A p.L318I | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV60481702; called by muse, mutect2
- DCDC1 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV60852406; called by muse, mutect2
- DHX33 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99834398; called by muse, mutect2, varscan2
- DIP2A | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1430660811, COSV59487332; called by muse, mutect2, varscan2
- DIPK1B | c.1012A>T p.T338S | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV63037762; called by muse, mutect2
- DMD | c.1149+1G>T p.X383_splice | Splice Site (SNP) | VAF 15/190 reads (8%) | catalogued as COSV55854988, COSV55874345; called by muse, mutect2
- DOCK2 | c.3311G>A p.R1104Q | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs149008494; called by muse, mutect2
- DSCAML1 | c.1441C>T p.P481S (on ENST00000321322; = p.P421S on NM_020693.4) | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1188072225, COSV100356001; called by muse, mutect2
- EIF4G1 | c.88C>G p.P30A | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV59993287; called by muse, mutect2, varscan2
- EMILIN2 | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV54424589; called by muse, mutect2
- ERCC6L | c.1405C>T p.L469F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1325461838; called by muse, mutect2, varscan2
- ESPNL | c.2971G>T p.A991S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs752488186; called by muse, mutect2
- FAM47C | c.1051G>C p.V351L | Missense Mutation (SNP) | VAF 29/420 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV63725090; called by muse, mutect2
- FAM50B | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs768080374, COSV66654570, COSV66655272; called by muse, mutect2, varscan2
- FASTKD1 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs748804138; called by muse, mutect2, varscan2
- FBN3 | c.4822G>T p.E1608* | Nonsense Mutation (SNP) | VAF 28/138 reads (20%) | catalogued as rs747253641, COSV54457613; called by muse, mutect2, varscan2
- FMN2 | c.3641G>T p.G1214V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.99); catalogued as COSV99070464; called by muse, mutect2, varscan2
- GABRG1 | c.1346C>A p.T449N | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1030733146; called by muse, mutect2
- GGT7 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1568933160; called by muse, mutect2
- GJB1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs864622215; called by muse, mutect2
- GLYATL2 | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as rs751684769, COSV54851332, COSV99780468; called by muse, mutect2
- GOLGB1 | c.8827C>G p.L2943V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100510461; called by muse, mutect2
- GRHL3 | c.249G>T p.R83S (on ENST00000350501 / NM_198174.3; = p.R88S on NM_021180.3) | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.162); catalogued as COSV52570393; called by muse, mutect2, varscan2
- GRIN2B | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101662962; called by muse, mutect2, varscan2
- GRIN3A | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 20/270 reads (7%) | catalogued as COSV62455915; called by muse, mutect2
- GSG1L | c.779G>T p.R260L (on ENST00000447459 / NM_001109763.2; = p.R105L on NM_144675.2) | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.758); catalogued as rs772785003, COSV66576535; called by muse, mutect2, varscan2
- HCN1 | c.1462C>A p.L488M | Missense Mutation (SNP) | VAF 88/519 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV57535187; called by muse, mutect2, varscan2
- HOXA1 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56067924; called by muse, mutect2, varscan2
- HOXC13 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV54497909; called by muse, mutect2, varscan2
- HSF1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs375270900; called by muse, mutect2
- HSPG2 | c.8653C>T p.P2885S | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.912); catalogued as COSV65934197; called by muse, mutect2, varscan2
- HTATSF1 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54479118; called by muse, mutect2
- IFNA4 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV101427028, COSV101427070; called by muse, mutect2
- IFT140 | c.69G>T p.W23C | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139141440; called by muse, mutect2, varscan2
- IL16 | c.2912G>T p.R971M (on ENST00000302987 / NM_172217.5; = p.R270M on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/310 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV57268465; called by muse, mutect2
- KDR | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.659); catalogued as COSV99818582, COSV99818918; called by muse, mutect2, varscan2
- KIF2B | c.587G>T p.R196M | Missense Mutation (SNP) | VAF 67/426 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV52127219; called by muse, mutect2, varscan2
- LCE4A | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs781282551, COSV100139976; called by muse, mutect2, varscan2
- LRRC7 | c.4363C>T p.P1455S (on ENST00000651989 / NM_001370785.2; = p.P1375S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/527 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV50409577; called by muse, mutect2
- MAGEL2 | c.935C>A p.A312E | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV58566886; called by muse, mutect2
- MAP2 | c.5165G>T p.R1722L | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52288792; called by muse, mutect2
- MED28 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV52845751; called by mutect2, varscan2
- MROH2A | c.2219C>T p.T740M | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs775574614; called by muse, mutect2, varscan2
- MTUS2 | c.2723G>T p.R908L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs542576593, COSV54984176, COSV99685789; called by muse, mutect2, varscan2
- MUC12 | c.11015C>A p.T3672K (on ENST00000379442; = p.T3529K on NM_001164462.1) | Missense Mutation (SNP) | VAF 66/1578 reads (4%) | SIFT tolerated (0.29); catalogued as COSV101060572; called by muse, mutect2
- MUC16 | c.21658G>T p.D7220Y | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV67466735; called by muse, mutect2, varscan2
- MUC16 | c.4564G>C p.G1522R | Missense Mutation (SNP) | VAF 22/289 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV67449958; called by muse, mutect2
- MUC4 | c.13136C>A p.P4379H (on ENST00000463781 / NM_018406.7; = p.P143H on NM_004532.6) | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs776029142; called by muse, mutect2, varscan2
- MYH13 | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52844410; called by muse, mutect2
- NBR1 | c.639G>T p.W213C | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100357767; called by muse, mutect2
- NEUROD4 | c.316G>C p.A106P | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54471548; called by muse, mutect2
- NLRP10 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 30/309 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60779511, COSV60781500; called by muse, mutect2
- NLRP2 | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs749931307, COSV54754287; called by muse, mutect2
- NTN4 | c.1168G>T p.D390Y | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.933); catalogued as COSV59218345; called by muse, mutect2
- OLFM3 | c.388C>A p.Q130K (on ENST00000338858 / NM_001288821.1; = p.Q110K on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/541 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.157); catalogued as COSV58795842; called by muse, mutect2
- OR14K1 | c.56G>A p.W19* | Nonsense Mutation (SNP) | VAF 15/128 reads (12%) | catalogued as rs868164296, COSV51720815; called by muse, mutect2, varscan2
- OR2A25 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV68717387; called by muse, mutect2
- OR2H1 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.609); catalogued as rs1200703071; called by muse, mutect2
- OR4C46 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 54/454 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV60219588; called by muse, mutect2, varscan2
- OR5M8 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 32/224 reads (14%) | catalogued as rs1412670746; called by muse, mutect2, varscan2
- PANK1 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as rs768514961; called by muse, mutect2, varscan2
- PCDH15 | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 29/458 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57317149; called by muse, mutect2
- PCDHB6 | c.815C>A p.S272* | Nonsense Mutation (SNP) | VAF 26/308 reads (8%) | catalogued as COSV50690449, COSV50693465; called by muse, mutect2
- PCDHB8 | c.1164G>T p.E388D | Missense Mutation (SNP) | VAF 78/734 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV50753831, COSV50830327; called by muse, mutect2, varscan2
- PCDHB9 | c.685C>A p.R229S | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.151); catalogued as rs782808992; called by muse, mutect2
- PCDHGB7 | c.1739G>T p.R580L | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV54013967; called by muse, mutect2, varscan2
- PKD1L1 | c.5822C>T p.S1941L | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781388062; called by muse, mutect2
- PLCL1 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as rs780710675; called by mutect2, varscan2
- PNLIP | c.284T>C p.I95T | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as rs1199156517; called by muse, mutect2, varscan2
- PNLIP | c.1351C>A p.P451T | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1302507809; called by muse, mutect2
- PRR9 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 27/498 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.982); catalogued as rs1177563968; called by muse, mutect2
- PTGES3L-AARSD1 | c.1497-1G>T p.X499_splice (on ENST00000421990 / NM_001136042.2; = p.X481_splice on NM_025267.3) | Splice Site (SNP) | VAF 14/104 reads (13%) | catalogued as rs200712342; called by muse, mutect2, varscan2
- RASSF2 | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs139690582; called by muse, mutect2
- REM1 | c.477C>G p.I159M | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV52426715; called by muse, mutect2, varscan2
- RET | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 58/478 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs149403911, COSV60692318; called by muse, mutect2, varscan2
- RGSL1 | c.201G>C p.W67C | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1467548612; called by muse, mutect2, varscan2
- RNF113A | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.044); catalogued as COSV65097562; called by muse, mutect2
- RYR2 | c.10339C>A p.Q3447K | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.724); catalogued as COSV100767334, COSV63675852; called by muse, mutect2, varscan2
- SEMA3C | c.2008G>T p.V670L | Missense Mutation (SNP) | VAF 34/419 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747781158; called by muse, mutect2
- SERINC5 | c.418G>T p.G140* | Nonsense Mutation (SNP) | VAF 15/340 reads (4%) | catalogued as COSV72595636; called by muse, mutect2
- SERPINB4 | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100345552, COSV100345889; called by muse, mutect2
- SGK2 | c.955G>A p.V319M | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as rs776480411; called by muse, mutect2
- SHANK2 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as COSV53605626; called by muse, mutect2, varscan2
- SLC26A5 | c.580G>C p.G194R | Missense Mutation (SNP) | VAF 21/283 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100100524; called by muse, mutect2
- SLC7A13 | c.274G>T p.V92F | Missense Mutation (SNP) | VAF 20/327 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as rs913031510, COSV52532636; called by muse, mutect2
- SMURF2 | c.1078A>C p.T360P | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1339401322; called by muse, mutect2, varscan2
- SPON1 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.071); catalogued as rs782545916, COSV100116076; called by muse, mutect2, varscan2
- SPPL3 | c.919G>C p.G307R | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99075594; called by muse, mutect2
- SPRY3 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1041058407, COSV57144214; called by muse, mutect2
- SSX1 | c.281-1G>A p.X94_splice | Splice Site (SNP) | VAF 10/215 reads (5%) | catalogued as rs1461562548; called by muse, mutect2
- STXBP3 | c.1275G>T p.R425S | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV64183710; called by muse, mutect2
- TANC1 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 27/398 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55098217; called by muse, mutect2
- TASOR2 | c.2326G>T p.G776W | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050115; called by muse, mutect2
- TCERG1L | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 12/166 reads (7%) | catalogued as rs867581672; called by muse, mutect2
- TCERG1L | c.531A>G p.I177M | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs986723560; called by muse, mutect2
- TCTN3 | c.1176G>T p.L392F | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs931265396; called by muse, mutect2
- TH | c.191G>T p.R64L (on ENST00000381178 / NM_199292.3; = p.R33L on NM_000360.4) | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV60766833; called by muse, mutect2, varscan2
- TM9SF4 | c.1084A>T p.I362F | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV54107741; called by muse, mutect2
- TP53 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 97/418 reads (23%) | catalogued as rs1555524156, COSV52716070, COSV52776099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPX2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1368516243, COSV100301938; called by muse, mutect2
- TRPC5 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 19/430 reads (4%) | catalogued as COSV99460261; called by muse, mutect2
- TRPM1 | c.3487G>T p.V1163L | Missense Mutation (SNP) | VAF 56/664 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs771496427, COSV56638810; called by muse, mutect2
- TSPAN32 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 6/81 reads (7%) | catalogued as COSV51718964; called by muse, mutect2
- TTC30A | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 11/153 reads (7%) | catalogued as COSV53700469; called by muse, mutect2
- TULP1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.054); catalogued as rs753258431; called by muse, mutect2, varscan2
- USH1C | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV99140384; called by muse, mutect2
- USH1G | c.1280G>C p.R427P | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV58881258; called by muse, mutect2
- VWDE | c.2549G>T p.W850L | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1188836530; called by muse, mutect2, varscan2
- WASHC5 | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV59199407; called by muse, mutect2
- WNK1 | c.4229C>T p.S1410F (on ENST00000315939 / NM_018979.4; = p.S1163F on NM_014823.3) | Missense Mutation (SNP) | VAF 53/455 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as rs750039108; called by muse, varscan2
- XDH | c.2900G>T p.R967I | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767514515; called by muse, mutect2, varscan2
- XPC | c.1111A>T p.T371S | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as CD162669; called by muse, mutect2
- ZFHX4 | c.2106G>T p.E702D | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV99029599; called by muse, mutect2, varscan2
- ZFHX4 | c.2107G>T p.V703F | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1266007787, COSV99267830; called by muse, mutect2, varscan2
- ZNF385D | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99874454; called by muse, mutect2, varscan2
- ZNF555 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 25/348 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs769535227; called by muse, mutect2
- ZNF695 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as rs536708166; called by muse, mutect2, varscan2
- ZNF804A | c.3620C>A p.P1207H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56470986; called by muse, mutect2
- ZP2 | c.257C>A p.P86Q | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.286); catalogued as COSV54816414, COSV99559600; called by muse, mutect2, varscan2
- ABCC12 | c.2798A>T p.Q933L | Missense Mutation (SNP) | VAF 36/464 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2
- ABI1 | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, mutect2
- AC011005.1 | c.259A>G p.K87E | Missense Mutation (SNP) | VAF 26/357 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ACAN | c.2543T>C p.V848A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2
- ADAMTS2 | c.1969C>A p.L657M | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS2 | c.1968C>A p.H656Q | Missense Mutation (SNP) | VAF 28/373 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2
- ADAMTS20 | c.1998C>A p.F666L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- ADD2 | c.636C>A p.H212Q | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRA2 | c.1269C>G p.I423M | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADH1A | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 99/594 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ADH6 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2
- AFDN | c.2251G>C p.E751Q | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); called by muse, mutect2
- AGBL3 | c.875C>A p.T292N | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2
- AGMO | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- AHNAK2 | c.10361G>T p.R3454L | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2
- ALKAL1 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 24/302 reads (8%) | called by muse, mutect2
- ANK2 | c.2962G>T p.G988W | Missense Mutation (SNP) | VAF 39/599 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKUB1 | c.998T>A p.F333Y | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANO3 | c.1257T>A p.Y419* | Nonsense Mutation (SNP) | VAF 19/206 reads (9%) | called by muse, mutect2
- ANTXR2 | c.955A>C p.I319L | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANXA8L1 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 28/558 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.934); called by muse, mutect2
- APOA4 | c.856C>G p.Q286E | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.792); called by muse, mutect2
- ARHGAP17 | c.1182G>T p.M394I | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ARMC4 | c.1995C>A p.Y665* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- ARMCX6 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ARX | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2
- ASB18 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.273); called by muse, mutect2
- ASB5 | c.934C>A p.L312I | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ATG2B | c.2028A>T p.K676N | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); called by muse, mutect2
- ATP2B2 | c.2332G>A p.A778T (on ENST00000352432; = p.A744T on NM_001683.5) | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCL2L12 | c.823del p.E275Sfs*8 | Frame Shift Del (DEL) | VAF 18/160 reads (11%) | called by mutect2, pindel, varscan2
- BMP3 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BMPR1B | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 17/165 reads (10%) | called by muse, mutect2, varscan2
- BOD1L1 | c.5134G>T p.G1712* | Nonsense Mutation (SNP) | VAF 27/450 reads (6%) | called by muse, mutect2
- BOP1 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 114/495 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BPIFA3 | c.218C>G p.A73G | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- BPNT2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2
- BTK | c.1629C>A p.S543= | Splice Region (SNP) | VAF 25/407 reads (6%) | called by muse, mutect2
- C10orf90 | c.680C>G p.A227G | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- C19orf12 | c.454G>A p.D152N (on ENST00000392278 / NM_001031726.3; = p.D141N on NM_031448.6) | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.235); called by muse, mutect2
- C5orf51 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 27/599 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.346); called by muse, mutect2
- CA3 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 40/470 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1E | c.2116C>G p.L706V | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- CACNA1F | c.3761G>A p.W1254* | Nonsense Mutation (SNP) | VAF 22/502 reads (4%) | called by muse, mutect2
- CAGE1 | c.642G>T p.K214N (on ENST00000512086; = p.K78N on NM_205864.3) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.211); called by muse, mutect2
- CASD1 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); called by muse, mutect2
- CATSPER2 | c.1373G>A p.R458K (on ENST00000321596 / NM_001282309.3; = p.R460K on NM_172095.4) | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.083); called by muse, mutect2
- CCNB3 | c.2082G>T p.L694F | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CCNB3 | c.3062C>G p.T1021S | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.043); called by muse, mutect2
- CDAN1 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 11/253 reads (4%) | called by muse, mutect2
- CDC20B | c.248G>T p.R83M | Missense Mutation (SNP) | VAF 26/457 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2
- CDH23 | c.3430+1del | Frame Shift Del (DEL) | VAF 25/204 reads (12%) | called by mutect2, varscan2
- CDH23 | c.8363T>A p.L2788Q | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); called by muse, mutect2
- CDHR4 | c.757A>T p.S253C | Missense Mutation (SNP) | VAF 13/251 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- CDIPT | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CECR2 | c.166A>G p.I56V | Missense Mutation (SNP) | VAF 47/349 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- CELF4 | c.796C>A p.Q266K | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CENPC | c.1444+1del p.X482_splice | Splice Site (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- CGN | c.2870A>T p.Q957L | Missense Mutation (SNP) | VAF 40/760 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CHRM3 | c.1471C>A p.Q491K | Missense Mutation (SNP) | VAF 48/642 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.268); called by muse, mutect2
- CIB4 | c.237G>T p.M79I | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLCNKB | c.758T>A p.L253Q | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLK2 | c.1263G>T p.W421C (on ENST00000368361 / NM_001294339.2; = p.W420C on NM_003993.4) | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNGA4 | c.1694G>T p.R565M | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CNTFR | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 22/356 reads (6%) | called by muse, mutect2
- CNTNAP5 | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL20A1 | c.379A>T p.R127W | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- COL22A1 | c.4472A>T p.Y1491F | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2
- COL5A2 | c.3769G>C p.A1257P | Missense Mutation (SNP) | VAF 73/727 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.188); called by muse, mutect2
- CORO6 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2
- CPNE4 | c.1025T>C p.L342S | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRACD | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 27/316 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2
- CRX | c.179A>T p.K60M | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSE1L | c.1927G>C p.A643P | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- CSMD3 | c.10436C>A p.P3479H (on ENST00000297405 / NM_001363185.1; = p.P3310H on NM_052900.3) | Missense Mutation (SNP) | VAF 23/461 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); called by muse, mutect2
- CSMD3 | c.9712C>A p.Q3238K (on ENST00000297405 / NM_001363185.1; = p.Q3069K on NM_052900.3) | Missense Mutation (SNP) | VAF 77/326 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- DCDC1 | c.2203T>C p.S735P | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2
- DENND2B | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- DENND2B | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- DGKI | c.1589A>G p.Y530C | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX34 | c.593A>T p.Y198F | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.903); called by muse, mutect2
- DLX1 | c.249C>A p.Y83* | Nonsense Mutation (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- DNAH11 | c.5095-1G>T p.X1699_splice | Splice Site (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- DOCK2 | c.1843+2T>A p.X615_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- DPEP1 | c.998G>A p.W333* | Nonsense Mutation (SNP) | VAF 35/163 reads (21%) | called by muse, mutect2, varscan2
- DPP10 | c.2198A>G p.Q733R | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSP | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 42/570 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.694); called by muse, mutect2
- DSP | c.418A>T p.K140* | Nonsense Mutation (SNP) | VAF 40/568 reads (7%) | called by muse, mutect2
- DST | c.16553C>T p.T5518I (on ENST00000361203 / NM_001374722.1; = p.T3106I on NM_015548.5) | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2
- DST | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DYSF | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- E2F7 | c.1233T>A p.F411L | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ELMO1 | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 33/366 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.052); called by muse, mutect2
- ELP2 | c.2459G>T p.R820I | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2
- EP400 | c.4111-2A>T p.X1371_splice | Splice Site (SNP) | VAF 39/233 reads (17%) | called by muse, mutect2, varscan2
- EPG5 | c.3586G>T p.A1196S | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2
- EPHA6 | c.2146T>C p.F716L (on ENST00000389672 / NM_001080448.3; = p.F108L on NM_173655.4) | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EPHB1 | c.1320G>T p.M440I | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.035); called by muse, mutect2
- ERVW-1 | c.197C>A p.T66N | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- ETNPPL | c.1433C>A p.P478H | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FANCB | c.1653G>C p.R551S | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- FBLN1 | c.939G>C p.L313F | Missense Mutation (SNP) | VAF 16/462 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- FBXL7 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2
- FCRL3 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.596); called by muse, mutect2
- FER1L6 | c.3919G>T p.E1307* | Nonsense Mutation (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- FFAR2 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 40/389 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FLG2 | c.6176G>A p.G2059E | Missense Mutation (SNP) | VAF 30/883 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.144); called by muse, mutect2
- FLG2 | c.3834T>A p.S1278R | Missense Mutation (SNP) | VAF 84/368 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FNIP2 | c.3034C>T p.Q1012* | Nonsense Mutation (SNP) | VAF 23/330 reads (7%) | called by muse, mutect2
- FOXO6 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.39); called by muse, mutect2, varscan2
- FPR3 | c.398C>A p.A133D | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FRYL | c.3703G>T p.E1235* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- FZD7 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- GABRA6 | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.151); called by muse, mutect2
- GAD2 | c.1158G>T p.R386S | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2
- GGN | c.1403dup p.L469Sfs*38 | Frame Shift Ins (INS) | VAF 10/92 reads (11%) | called by mutect2, pindel, varscan2
- GLIS3 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLS | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2
- GON4L | c.482G>T p.S161I | Missense Mutation (SNP) | VAF 13/343 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2
- GPAT3 | c.566G>T p.W189L | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- GPR139 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 48/350 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.034); called by mutect2, varscan2
- GRAMD1B | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2
- GRM2 | c.2423G>T p.C808F | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2
- HAUS3 | c.194A>C p.Q65P | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- HCN4 | c.807G>T p.M269I | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HECW2 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- HEPACAM2 | c.1202G>T p.G401V (on ENST00000394468 / NM_001039372.4; = p.G389V on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HERC1 | c.8924G>T p.R2975M | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2
- HHIPL1 | c.1687A>T p.T563S | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.284); called by muse, mutect2
- HIVEP3 | c.7216G>T p.A2406S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HLA-DPB1 | c.758-1G>C p.X253_splice | Splice Site (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- HMCN2 | c.13985G>T p.W4662L | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.063); called by muse, mutect2
- HOXD1 | c.965C>G p.S322C | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- HPS1 | c.1744-6C>G | Splice Region (SNP) | VAF 35/382 reads (9%) | called by muse, mutect2
- HTR2C | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR3B | c.1288A>G p.T430A | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HYDIN | c.3753G>T p.E1251D | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHM | c.1400C>G p.T467S | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- IGKV2D-24 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 38/329 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- IHO1 | c.291A>G p.I97M | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.127); called by muse, mutect2
- INHBB | c.520G>C p.V174L | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- IREB2 | c.670A>T p.R224* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- ITGA2B | c.2205G>T p.L735F | Missense Mutation (SNP) | VAF 33/474 reads (7%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.732); called by muse, mutect2
- ITIH3 | c.885G>T p.M295I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAKMIP1 | c.1790G>T p.R597I | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KCNA4 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KCNH5 | c.2635G>T p.G879W | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- KCNH8 | c.1351T>A p.S451T | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); called by muse, mutect2
- KHDRBS2 | c.745G>T p.G249W | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIF19 | c.2414C>A p.T805K | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF21B | c.2372A>T p.Q791L | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- KIF2B | c.320G>T p.R107M | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- KIF2B | c.1377G>T p.K459N | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2
- KIF7 | c.1768G>A p.G590S | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- KLHL38 | c.1711C>G p.L571V | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.404); called by muse, mutect2
- KRT2 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 33/474 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRT3 | c.548T>G p.L183R | Missense Mutation (SNP) | VAF 44/398 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRT37 | c.1338C>A p.S446R | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KRT6C | c.1600G>T p.A534S | Missense Mutation (SNP) | VAF 52/661 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- KRTAP10-11 | c.552C>A p.Y184* | Nonsense Mutation (SNP) | VAF 144/643 reads (22%) | called by muse, mutect2, varscan2
- LAPTM5 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2, varscan2
- LEUTX | c.293G>T p.S98I | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LGI1 | c.934G>C p.D312H | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.316); called by muse, mutect2
- LINS1 | c.2101G>T p.D701Y | Missense Mutation (SNP) | VAF 24/566 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2
- LNPK | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2
- LRCH1 | c.1208G>T p.R403I | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2
- LRP1B | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 32/560 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRP4 | c.5074G>T p.E1692* | Nonsense Mutation (SNP) | VAF 22/294 reads (7%) | called by muse, mutect2
- LRRC66 | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC7 | c.1153G>T p.V385L (on ENST00000651989 / NM_001370785.2; = p.V352L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.086); called by muse, mutect2
- LRRC7 | c.1154T>G p.V385G (on ENST00000651989 / NM_001370785.2; = p.V352G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- MACF1 | c.13889G>T p.R4630L (on ENST00000372915; = p.R2563L on NM_012090.5) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- MAGEC2 | c.651G>C p.E217D | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.11); called by muse, mutect2
- MAMLD1 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.236); called by muse, mutect2
- MAN2A2 | c.3110G>A p.G1037D | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.062); called by muse, mutect2
- MARCHF11 | c.1083G>T p.Q361H | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2
- MARCO | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MARK4 | c.2105G>T p.G702V | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MBD1 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MID1 | c.1650C>G p.S550R | Missense Mutation (SNP) | VAF 16/375 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- MLYCD | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 12/145 reads (8%) | called by muse, mutect2
- MMP16 | c.1343T>G p.V448G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.405); called by muse, mutect2
- MPDZ | c.2933G>T p.G978V | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MRC1 | c.3977C>A p.S1326Y | Missense Mutation (SNP) | VAF 65/692 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- MRPL46 | c.48G>T p.W16C | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- MRPS7 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MXRA5 | c.7718G>T p.S2573I | Missense Mutation (SNP) | VAF 76/399 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- MYH7 | c.5126C>A p.T1709N | Missense Mutation (SNP) | VAF 113/552 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- MYH8 | c.4849G>T p.V1617F | Missense Mutation (SNP) | VAF 63/384 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYT1 | c.3266C>T p.A1089V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- NAGS | c.323C>G p.A108G | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- NBPF12 | c.1013T>C p.I338T | Missense Mutation (SNP) | VAF 62/1424 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.318); called by muse, mutect2
- NBPF3 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NCAN | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NHS | c.4583C>T p.P1528L | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2
- NINL | c.3239A>T p.E1080V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NISCH | c.1666G>T p.D556Y | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NLGN1 | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- NTRK3 | c.1979C>A p.A660D | Missense Mutation (SNP) | VAF 43/354 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NTSR1 | c.5G>T p.R2L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NWD2 | c.825G>T p.M275I | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); called by muse, mutect2
- NWD2 | c.2332G>T p.E778* | Nonsense Mutation (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- OPTC | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 58/606 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR10J3 | c.542A>T p.D181V | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR14I1 | c.416G>C p.C139S | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR1S2 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 50/602 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.057); called by muse, mutect2
- OR2B2 | c.305T>G p.F102C | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- OR2G2 | c.302T>A p.L101* | Nonsense Mutation (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- OR2M2 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.003); called by muse, mutect2
- OR2T10 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.662); called by mutect2, varscan2
- OR4C13 | c.625T>A p.C209S | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- OR4K14 | c.411G>T p.M137I | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.272); called by muse, mutect2
- OR52A1 | c.695C>A p.P232H | Missense Mutation (SNP) | VAF 17/345 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- OR5AP2 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- OR5F1 | c.593T>A p.I198K | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- OR8J1 | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR8U1 | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OTOA | c.290del p.E97Gfs*14 | Frame Shift Del (DEL) | VAF 45/454 reads (10%) | called by mutect2, pindel, varscan2
- OTOF | c.95C>A p.S32Y | Missense Mutation (SNP) | VAF 53/492 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PABPC4L | c.1029G>T p.E343D | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.041); called by muse, mutect2
- PADI2 | c.1837T>A p.C613S | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.947T>A p.I316N (on ENST00000259318 / NM_001136562.3; = p.I547N on NM_007203.5) | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- PCDHB7 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 10/243 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); called by muse, mutect2
- PCDHB7 | c.617C>A p.P206Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PCSK1 | c.1709G>C p.R570T | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- PCSK1 | c.251T>C p.F84S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDZD8 | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- PGAP1 | c.1034-2A>T p.X345_splice | Splice Site (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- PHTF2 | c.731G>T p.G244V (on ENST00000248550 / NM_001366089.1; = p.G206V on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); called by muse, mutect2
- PIK3CG | c.3245T>C p.V1082A | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PKD1L1 | c.2524C>A p.L842M | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.247); called by muse, mutect2
- PKNOX2 | c.467A>T p.K156M | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PLXNA3 | c.3984G>T p.K1328N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- PLXNA3 | c.5099A>T p.Q1700L | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PLXNA4 | c.3493G>T p.G1165C | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PNLIP | c.1352C>A p.P451Q | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- PPARD | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPARD | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PPFIA4 | c.2888G>T p.S963I (on ENST00000447715; = p.S964I on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/309 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PPP1R12C | c.2263-2dup p.X755_splice | Splice Site (INS) | VAF 12/76 reads (16%) | called by mutect2, pindel, varscan2
- PPP1R26 | c.2539G>T p.E847* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- PRDM13 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PROM2 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 40/396 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PROS1 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR12 | c.3040G>T p.A1014S (on ENST00000615927; = p.A1835S on NM_020719.3) | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- PRSS36 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 27/400 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.06); called by muse, mutect2
- PTGS1 | c.960del p.T321Pfs*16 | Frame Shift Del (DEL) | VAF 18/134 reads (13%) | called by mutect2, pindel, varscan2
- PTPRQ | c.6761A>G p.N2254S (on ENST00000616559; = p.N2221S on NM_001145026.2) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- RANBP17 | c.3159G>T p.K1053N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- RBMXL3 | c.1191_1192insAACGCCCACAGCGGAGGCCGCTCGCAC p.P397_D398insNAHSGGRSH | In Frame Ins (INS) | VAF 10/111 reads (9%) | called by mutect2, pindel
- REEP6 | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RET | c.683C>A p.A228D | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- RFXANK | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 70/494 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RGS9 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 63/375 reads (17%) | called by muse, mutect2, varscan2
- RHD | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 47/392 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RICTOR | c.218G>T p.S73I | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.198); called by muse, mutect2
- RLIM | c.1445G>A p.G482D | Missense Mutation (SNP) | VAF 12/396 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- RNF39 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2
- RREB1 | c.4747G>A p.E1583K | Missense Mutation (SNP) | VAF 35/399 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.216); called by muse, mutect2
- RSF1 | c.1517C>T p.T506I | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTL3 | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- SALL1 | c.2508C>A p.S836R | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- SALL3 | c.2773C>A p.P925T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SAMD9L | c.2072G>T p.G691V | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SATB2 | c.1426G>T p.V476L | Missense Mutation (SNP) | VAF 44/519 reads (8%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.559); called by muse, mutect2
- SBK2 | c.587G>T p.C196F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SCN3B | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 44/761 reads (6%) | called by muse, mutect2
- SESN3 | c.880A>G p.K294E | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.092); called by muse, mutect2
- SETX | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHC1 | c.1609G>T p.D537Y (on ENST00000368445 / NM_183001.5; = p.D428Y on NM_003029.5) | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SI | c.2828G>T p.C943F | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIGLEC1 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SIGLEC7 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.67); called by muse, mutect2
- SIPA1L2 | c.3004C>G p.L1002V | Missense Mutation (SNP) | VAF 40/469 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC17A2 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A3 | c.94A>T p.S32C | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.205); called by muse, mutect2
- SLC2A10 | c.1285C>G p.P429A | Missense Mutation (SNP) | VAF 33/347 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC5A4 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A5 | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 43/368 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO6A1 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.163); called by muse, mutect2
- SLITRK3 | c.2566G>C p.D856H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNAPC4 | c.470T>A p.V157E | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- SNX25 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- SOWAHB | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2
- SOX13 | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); called by muse, mutect2
- SP3 | c.1156A>T p.I386F | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.795); called by muse, mutect2
- SPATA31A6 | c.2478G>C p.K826N | Missense Mutation (SNP) | VAF 72/469 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SPATA31A6 | c.3163C>A p.Q1055K | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.439); called by mutect2, varscan2
- SPATA31D1 | c.4280G>C p.C1427S | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.058); called by muse, mutect2
- SPG7 | c.1112T>C p.F371S (on ENST00000268704; = p.F378S on NM_003119.4) | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPTA1 | c.6527C>A p.T2176N | Missense Mutation (SNP) | VAF 34/558 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2
- SRCAP | c.1319-1G>T p.X440_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- STYXL2 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 154/604 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SUCLG1 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 77/600 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SYNCRIP | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.179); called by muse, mutect2
- TBC1D15 | c.446A>T p.Y149F | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.992); called by muse, mutect2
- TBX3 | c.2069C>A p.S690Y (on ENST00000257566 / NM_016569.4; = p.S670Y on NM_005996.4) | Missense Mutation (SNP) | VAF 40/468 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TCEAL4 | c.70C>G p.P24A | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- TERT | c.2032G>T p.A678S | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.279); called by muse, mutect2
- TEX13C | c.782C>A p.A261E | Missense Mutation (SNP) | VAF 42/453 reads (9%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.893); called by muse, mutect2
- TIAM2 | c.700C>G p.R234G | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TLCD4 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMCO1 | c.388A>T p.N130Y (on ENST00000612311 / NM_001256164.1; = p.N79Y on NM_019026.6) | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- TMEM132E | c.1097T>C p.L366P (on ENST00000321639; = p.L456P on NM_001304438.2) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TMEM8B | c.901G>T p.G301C | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNKS | c.2139A>T p.K713N | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); called by muse, mutect2
- TRBV7-1 | c.287T>A p.L96Q | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRIM9 | c.592del p.H198Tfs*7 | Frame Shift Del (DEL) | VAF 20/190 reads (11%) | called by mutect2, varscan2
- TRIML2 | c.299dup p.N100Kfs*3 | Frame Shift Ins (INS) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- TSEN2 | c.810G>T p.R270S | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TSHZ3 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- UNC79 | c.7255C>A p.L2419M (on ENST00000393151 / NM_001346218.2; = p.L2242M on NM_020818.5) | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UPF3B | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USP11 | c.2098A>G p.N700D (on ENST00000218348; = p.N657D on NM_001371072.1) | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.519); called by muse, mutect2
- USP43 | c.2536A>T p.S846C | Missense Mutation (SNP) | VAF 19/252 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2
- USP7 | c.2077G>T p.D693Y | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UTS2R | c.331T>A p.Y111N | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- VCAM1 | c.287C>A p.T96K | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- VIRMA | c.3542G>T p.C1181F | Missense Mutation (SNP) | VAF 28/317 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- VPS13B | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- VPS16 | c.1714G>T p.D572Y | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- VSIG10 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 27/492 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- VSX1 | c.223C>A p.R75S | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.066); called by muse, mutect2
- VWA3A | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- WAC | c.1036T>C p.S346P | Missense Mutation (SNP) | VAF 62/588 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- WASH6P | c.1402C>G p.Q468E | Missense Mutation (SNP) | VAF 21/648 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.159); called by muse, mutect2
- WDR81 | c.2170G>T p.G724C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- YWHAG | c.53A>T p.E18V | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); called by muse, mutect2
- ZBTB20 | c.1195G>C p.A399P (on ENST00000474710 / NM_001164342.2; = p.A326P on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2
- ZFPM2 | c.2322A>T p.Q774H | Missense Mutation (SNP) | VAF 50/792 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); called by muse, mutect2
- ZMYM3 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.059); called by muse, mutect2
- ZNF175 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF208 | c.3523G>T p.G1175C | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF250 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 15/350 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF292 | c.5799G>A p.M1933I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ZNF365 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 15/192 reads (8%) | called by muse, mutect2
- ZNF407 | c.5434G>T p.V1812F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF426 | c.1488G>T p.R496S | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ZNF436 | c.722A>G p.Q241R | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- ZNF454 | c.1237A>T p.R413* | Nonsense Mutation (SNP) | VAF 40/205 reads (20%) | called by muse, mutect2, varscan2
- ZNF469 | c.10535G>T p.G3512V (on ENST00000437464; = p.G3540V on NM_001367624.2) | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ZNF492 | c.1262A>G p.Y421C | Missense Mutation (SNP) | VAF 46/558 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF540 | c.1772G>T p.S591I | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2
- ZNF541 | c.2303G>T p.C768F | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ZNF551 | c.367C>G p.Q123E | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2
- ZNF566 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF585B | c.1580G>T p.C527F | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF679 | c.1024C>A p.H342N | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF98 | c.1385A>G p.Y462C | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSCAN26 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2, varscan2
- ABCD2 | c.168T>A p.A56= | Silent (SNP) | VAF 28/318 reads (9%) | called by muse, mutect2
- ABRA | c.72C>A p.T24= | Silent (SNP) | VAF 24/246 reads (10%) | catalogued as COSV100357625; called by muse, mutect2
- ADAMTS19 | c.2598T>C p.Y866= | Silent (SNP) | VAF 14/262 reads (5%) | catalogued as rs1026530550; called by muse, mutect2
- ADAMTS2 | c.2577C>A p.A859= | Silent (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.243A>G p.A81= | Silent (SNP) | VAF 8/141 reads (6%) | called by muse, mutect2
- ADGRE2 | c.1899G>A p.V633= | Silent (SNP) | VAF 53/521 reads (10%) | called by muse, mutect2, varscan2
- ANKRD17 | c.63G>T p.P21= | Silent (SNP) | VAF 9/130 reads (7%) | called by muse, mutect2
- AOC1 | c.1356G>T p.L452= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV100710733; called by muse, mutect2
- ARID4A | c.3579A>G p.L1193= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs755216548; called by mutect2, varscan2
- ARMC6 | c.465G>C p.L155= (on ENST00000392336; = p.L130= on NM_033415.4) | Silent (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- ARMCX2 | c.675G>A p.T225= | Silent (SNP) | VAF 18/259 reads (7%) | catalogued as rs1556061231, COSV57530679; called by muse, mutect2
- AVL9 | c.420A>G p.A140= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs1467401404; called by muse, mutect2, varscan2
- B4GALNT4 | c.471C>T p.A157= | Silent (SNP) | VAF 18/221 reads (8%) | catalogued as rs751338895, COSV57326716; called by muse, mutect2
- BAAT | c.1032G>A p.L344= | Silent (SNP) | VAF 54/730 reads (7%) | called by muse, mutect2
- BRD9 | c.1581G>T p.T527= | Silent (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- BRDT | c.1113G>A p.T371= | Silent (SNP) | VAF 21/154 reads (14%) | catalogued as rs745926830, COSV62864669; called by muse, mutect2, varscan2
- BTBD8 | c.4836A>G p.Q1612= (on ENST00000636805 / NM_001376131.1; = p.Q1099= on NM_015237.4) | Silent (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
- CACNA1B | c.588G>A p.V196= | Silent (SNP) | VAF 26/258 reads (10%) | called by muse, mutect2
- CACNA1B | c.678T>A p.I226= | Silent (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- CAND2 | c.2514G>T p.G838= (on ENST00000456430 / NM_001162499.2; = p.G745= on NM_012298.3) | Silent (SNP) | VAF 17/176 reads (10%) | called by muse, mutect2, varscan2
- CAPN10 | c.513G>T p.A171= | Silent (SNP) | VAF 23/210 reads (11%) | called by muse, mutect2, varscan2
- CBLB | c.1605C>T p.C535= | Silent (SNP) | VAF 22/293 reads (8%) | catalogued as rs1398511588; called by muse, mutect2
- CDH20 | c.645T>G p.S215= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as rs758546149; called by muse, mutect2, varscan2
- CIT | c.5898G>C p.L1966= | Silent (SNP) | VAF 28/140 reads (20%) | called by muse, mutect2, varscan2
- CNTN1 | c.2274A>T p.T758= | Silent (SNP) | VAF 20/349 reads (6%) | called by muse, mutect2
- COL27A1 | c.2859G>T p.P953= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs747181763; called by muse, mutect2, varscan2
- COL4A5 | c.1296G>T p.G432= | Silent (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
- CPE | c.870G>T p.P290= | Silent (SNP) | VAF 77/382 reads (20%) | catalogued as COSV68580851; called by muse, mutect2, varscan2
- CRISPLD1 | c.708A>G p.R236= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- CXCR2 | c.294C>A p.A98= | Silent (SNP) | VAF 40/243 reads (16%) | called by muse, mutect2, varscan2
- CXCR3 | c.222G>A p.V74= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- CYBB | c.1371G>T p.L457= | Silent (SNP) | VAF 63/617 reads (10%) | called by muse, mutect2
- CYSLTR2 | c.393G>A p.V131= | Silent (SNP) | VAF 16/428 reads (4%) | called by muse, mutect2
- DMBT1 | c.1597A>C p.R533= | Silent (SNP) | VAF 34/606 reads (6%) | catalogued as rs1156283113; called by muse, mutect2
- DNAAF2 | c.1749A>C p.T583= | Silent (SNP) | VAF 56/594 reads (9%) | called by muse, mutect2
- DNAAF5 | c.1146G>T p.L382= | Silent (SNP) | VAF 24/361 reads (7%) | called by muse, mutect2
- DPP6 | c.63C>A p.P21= | Silent (SNP) | VAF 25/338 reads (7%) | called by muse, mutect2
- DRD2 | c.474C>T p.I158= | Silent (SNP) | VAF 30/338 reads (9%) | catalogued as rs867715417; called by muse, mutect2
- EPHB1 | c.1824G>T p.R608= | Silent (SNP) | VAF 11/355 reads (3%) | catalogued as COSV67656595; called by muse, mutect2
- EPS8L2 | c.63C>T p.S21= | Silent (SNP) | VAF 24/287 reads (8%) | catalogued as rs574588438; called by muse, mutect2
- FAM171B | c.957A>T p.T319= | Silent (SNP) | VAF 26/190 reads (14%) | called by muse, mutect2, varscan2
- FAM47C | c.435C>T p.L145= | Silent (SNP) | VAF 9/155 reads (6%) | catalogued as COSV100792771; called by muse, mutect2
- FBLN2 | c.525C>A p.P175= | Silent (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- FCRL5 | c.1788C>T p.I596= | Silent (SNP) | VAF 20/182 reads (11%) | catalogued as COSV62515522; called by muse, mutect2, varscan2
- FGF14 | c.135C>T p.N45= | Silent (SNP) | VAF 42/434 reads (10%) | catalogued as rs1041531627; called by muse, mutect2
- GALP | c.225C>A p.L75= | Silent (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- GBP6 | c.1836T>G p.A612= | Silent (SNP) | VAF 25/293 reads (9%) | called by muse, mutect2
- GIMAP8 | c.972C>A p.P324= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as COSV100217582; called by muse, mutect2
- GIMAP8 | c.1407G>T p.R469= | Silent (SNP) | VAF 21/217 reads (10%) | called by muse, mutect2, varscan2
- GNA15 | c.414G>T p.L138= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- GPR119 | c.231G>T p.L77= | Silent (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- GPR139 | c.786G>T p.L262= | Silent (SNP) | VAF 48/342 reads (14%) | catalogued as rs1444754469; called by mutect2, varscan2
- GPR31 | c.351C>T p.V117= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- GRIN2D | c.601C>T p.L201= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as rs1436009369; called by muse, mutect2
- GRM6 | c.2055G>T p.S685= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as COSV51446113; called by muse, varscan2
- GULP1 | c.768A>T p.A256= | Silent (SNP) | VAF 11/139 reads (8%) | called by muse, mutect2
- H2BC18 | c.159C>T p.T53= | Silent (SNP) | VAF 30/800 reads (4%) | called by muse, mutect2
- HDAC6 | c.1645C>A p.R549= | Silent (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- HECW1 | c.4755G>T p.S1585= | Silent (SNP) | VAF 9/234 reads (4%) | catalogued as COSV101222900; called by muse, mutect2
- HHAT | c.948C>A p.L316= | Silent (SNP) | VAF 34/524 reads (6%) | called by muse, mutect2
- HHLA1 | c.856A>C p.R286= | Silent (SNP) | VAF 58/210 reads (28%) | catalogued as rs1427503081; called by muse, mutect2, varscan2
- HJV | c.411C>A p.G137= (on ENST00000336751 / NM_213653.4; = p.G24= on NM_145277.5) | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as rs782020534; called by muse, mutect2, varscan2
- HOXC12 | c.561C>A p.P187= | Silent (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2
- HYDIN | c.6552C>T p.P2184= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as rs368359335; called by muse, mutect2, varscan2
- IGLV2-11 | c.42C>A p.G14= | Silent (SNP) | VAF 38/480 reads (8%) | called by muse, mutect2
- IGLV2-14 | c.225G>T p.R75= | Silent (SNP) | VAF 156/748 reads (21%) | called by muse, mutect2
- IGSF9B | c.4248G>T p.P1416= | Silent (SNP) | VAF 21/259 reads (8%) | called by muse, mutect2
- IGSF9B | c.1413G>T p.G471= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- KIF19 | c.2415A>G p.T805= | Silent (SNP) | VAF 17/163 reads (10%) | called by muse, mutect2, varscan2
- KLHL30 | c.321A>C p.T107= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- KLK5 | c.438C>G p.S146= | Silent (SNP) | VAF 39/252 reads (15%) | called by muse, mutect2, varscan2
- LPA | c.3336T>C p.P1112= | Silent (SNP) | VAF 40/392 reads (10%) | called by muse, mutect2, varscan2
- MAMSTR | c.222T>A p.P74= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- MEGF6 | c.3024G>T p.G1008= | Silent (SNP) | VAF 16/155 reads (10%) | called by muse, mutect2, varscan2
- MUC16 | c.41835C>A p.G13945= | Silent (SNP) | VAF 17/173 reads (10%) | called by muse, mutect2, varscan2
- MXRA5 | c.5547T>G p.L1849= | Silent (SNP) | VAF 26/288 reads (9%) | called by muse, mutect2
- MYCBP2 | c.10917C>T p.A3639= (on ENST00000357337; = p.A3677= on NM_015057.5) | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- MYH11 | c.4461C>G p.S1487= | Silent (SNP) | VAF 66/480 reads (14%) | catalogued as rs776746865; called by muse, mutect2, varscan2
- NAV3 | c.5022T>C p.S1674= | Silent (SNP) | VAF 25/185 reads (14%) | catalogued as rs750869209; called by muse, mutect2, varscan2
- NBEAL1 | c.3540C>A p.L1180= | Silent (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2, varscan2
- NKX3-2 | c.210G>C p.L70= | Silent (SNP) | VAF 15/226 reads (7%) | called by muse, mutect2
- NOBOX | c.1638C>A p.P546= | Silent (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- NOS2 | c.2118G>T p.P706= | Silent (SNP) | VAF 32/368 reads (9%) | called by muse, mutect2
- NRXN1 | c.2646G>C p.L882= | Silent (SNP) | VAF 24/324 reads (7%) | catalogued as rs758444872; called by muse, mutect2
- OPRK1 | c.981C>A p.P327= | Silent (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- OR10P1 | c.270C>A p.P90= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV59008555; called by muse, mutect2, varscan2
- OR1J2 | c.144C>A p.L48= | Silent (SNP) | VAF 20/244 reads (8%) | catalogued as COSV58945200; called by muse, mutect2
- OR2T10 | c.24G>C p.L8= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV100393836; called by muse, mutect2, varscan2
- OR2V2 | c.342C>A p.L114= | Silent (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- OR2W3 | c.273C>A p.T91= | Silent (SNP) | VAF 28/326 reads (9%) | called by muse, mutect2
- OR52A1 | c.696C>A p.P232= | Silent (SNP) | VAF 18/346 reads (5%) | catalogued as COSV61093303; called by muse, mutect2
- OR6N1 | c.156C>T p.D52= | Silent (SNP) | VAF 19/292 reads (7%) | called by muse, mutect2
- PARN | c.1162C>T p.L388= | Silent (SNP) | VAF 28/306 reads (9%) | catalogued as rs750051082; called by muse, mutect2
- PCDH10 | c.1608G>A p.L536= | Silent (SNP) | VAF 18/238 reads (8%) | catalogued as rs1271526345, COSV52094564; called by muse, mutect2
- PCDHB11 | c.1101T>A p.V367= | Silent (SNP) | VAF 24/261 reads (9%) | called by muse, mutect2
- PCDHB7 | c.618A>G p.P206= | Silent (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1782C>T p.D594= | Silent (SNP) | VAF 40/804 reads (5%) | catalogued as rs782178135, COSV50797442; called by muse, mutect2
- PCDHGB4 | c.402G>T p.T134= | Silent (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- PCNX2 | c.960C>T p.A320= | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as rs896866089; called by muse, mutect2
- PGAM4 | c.744C>A p.A248= | Silent (SNP) | VAF 14/287 reads (5%) | called by muse, mutect2
- PHOSPHO1 | c.456G>A p.P152= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV56799548; called by muse, mutect2, varscan2
- PLXDC1 | c.1317C>G p.A439= | Silent (SNP) | VAF 27/222 reads (12%) | called by muse, mutect2, varscan2
- PPP3CA | c.1164A>T p.T388= | Silent (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- PRAMEF20 | c.1098C>A p.V366= | Silent (SNP) | VAF 82/841 reads (10%) | called by muse, mutect2
- PRUNE2 | c.2052A>G p.E684= | Silent (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- PTGIR | c.615G>A p.S205= | Silent (SNP) | VAF 16/163 reads (10%) | catalogued as rs202124970; called by muse, mutect2
- QSOX1 | c.1051C>T p.L351= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV62580383; called by muse, mutect2, varscan2
- RBFOX1 | c.213G>A p.T71= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs1433814435, COSV60958631; called by muse, mutect2, varscan2
- RBM22 | c.210G>T p.V70= | Silent (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- RCC2 | c.1197C>T p.V399= | Silent (SNP) | VAF 22/324 reads (7%) | called by muse, mutect2
- RMND5A | c.117C>T p.L39= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as COSV52153767; called by muse, mutect2, varscan2
- RNF39 | c.75G>A p.A25= | Silent (SNP) | VAF 50/495 reads (10%) | called by muse, mutect2, varscan2
- SATB1 | c.1716C>T p.N572= | Silent (SNP) | VAF 30/378 reads (8%) | catalogued as rs780251058, COSV100113319, COSV58673929; called by muse, mutect2
- SERPINB4 | c.183A>G p.Q61= | Silent (SNP) | VAF 34/282 reads (12%) | catalogued as rs564224159; called by muse, mutect2
- SERPINE3 | c.30C>A p.L10= | Silent (SNP) | VAF 11/132 reads (8%) | called by muse, mutect2
- SGK2 | c.954A>T p.T318= | Silent (SNP) | VAF 19/231 reads (8%) | called by muse, mutect2
- SHISAL1 | c.54G>A p.L18= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV66988825; called by muse, mutect2, varscan2
- SLC16A2 | c.267G>A p.A89= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as rs996029350, COSV99330683; called by muse, mutect2
- SLC25A23 | c.609G>A p.T203= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as rs377109434; called by muse, mutect2, varscan2
- SLC5A5 | c.876C>T p.I292= | Silent (SNP) | VAF 36/398 reads (9%) | catalogued as rs750552838, COSV55835831; called by muse, mutect2
- SLC7A13 | c.273G>T p.T91= | Silent (SNP) | VAF 20/332 reads (6%) | catalogued as rs753682037, COSV52537724, COSV99878997; called by muse, mutect2
- SMYD4 | c.1137C>T p.I379= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV59713715; called by muse, mutect2, varscan2
- SNX29 | c.678C>T p.A226= | Silent (SNP) | VAF 27/590 reads (5%) | catalogued as rs1179338103, COSV100027794; called by muse, mutect2
- SOX17 | c.1020G>A p.L340= | Silent (SNP) | VAF 69/292 reads (24%) | catalogued as rs1272321292; called by muse, mutect2, varscan2
- ST18 | c.3132T>A p.G1044= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, varscan2
- SULT1B1 | c.387G>T p.L129= | Silent (SNP) | VAF 34/323 reads (11%) | called by muse, varscan2
- SYT10 | c.1512G>T p.R504= | Silent (SNP) | VAF 28/382 reads (7%) | called by muse, mutect2
- SYTL2 | c.1482T>A p.P494= | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- TANC2 | c.402G>T p.L134= | Silent (SNP) | VAF 34/332 reads (10%) | called by muse, mutect2
- TBC1D3I | c.319C>A p.R107= | Silent (SNP) | VAF 44/290 reads (15%) | called by muse, mutect2, varscan2
- TCF24 | c.348G>T p.G116= | Silent (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- TEX55 | c.1044C>T p.H348= | Silent (SNP) | VAF 31/238 reads (13%) | called by muse, mutect2, varscan2
- TMEM229B | c.306C>A p.P102= | Silent (SNP) | VAF 30/342 reads (9%) | called by muse, mutect2
- TOMM6 | c.201C>T p.L67= | Silent (SNP) | VAF 33/320 reads (10%) | called by muse, mutect2, varscan2
- TRAV9-1 | c.37T>C p.L13= | Silent (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- TRIM77 | c.1125C>A p.I375= | Silent (SNP) | VAF 19/137 reads (14%) | called by muse, mutect2, varscan2
- TRPV6 | c.1936C>A p.R646= | Silent (SNP) | VAF 32/394 reads (8%) | catalogued as COSV63894363; called by muse, mutect2
- TSHZ3 | c.3057A>G p.A1019= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as rs1212651930; called by muse, mutect2
- TSPAN5 | c.264T>C p.T88= | Silent (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- TUB | c.48C>A p.A16= | Silent (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2
- UNC5A | c.2430G>T p.R810= | Silent (SNP) | VAF 22/168 reads (13%) | called by muse, mutect2, varscan2
- USH2A | c.4044G>T p.V1348= | Silent (SNP) | VAF 7/158 reads (4%) | called by muse, mutect2
- VPS13B | c.9255G>A p.Q3085= | Silent (SNP) | VAF 10/313 reads (3%) | called by muse, mutect2
- ZAN | c.3363C>A p.P1121= | Silent (SNP) | VAF 20/172 reads (12%) | catalogued as COSV100769777; called by muse, mutect2
- ZDHHC3 | c.843C>T p.A281= (on ENST00000424952 / NM_001135179.2; = p.A309= on NM_016598.3) | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- ZFHX4 | c.7467G>A p.Q2489= | Silent (SNP) | VAF 16/246 reads (7%) | catalogued as COSV99266156; called by muse, mutect2
- ZNF114 | c.33G>T p.V11= | Silent (SNP) | VAF 16/276 reads (6%) | called by muse, mutect2
- ZNF408 | c.1215G>T p.G405= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV61238038; called by muse, mutect2, varscan2
- ZNF646 | c.3639G>A p.K1213= | Silent (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- ZNF729 | c.2721C>A p.P907= | Silent (SNP) | VAF 40/250 reads (16%) | called by muse, mutect2, varscan2
- ZNF777 | c.1770G>T p.T590= | Silent (SNP) | VAF 44/450 reads (10%) | called by muse, mutect2
- ABTB1 | c.-50C>A | 5'UTR (SNP) | VAF 19/136 reads (14%) | catalogued as rs1559882692; called by muse, mutect2, varscan2
- AC004890.2 | n.1349C>T | RNA (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- ACADM | c.1194+54G>T | Intron (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- AL121899.2 | c.*311C>T | 3'UTR (SNP) | VAF 31/272 reads (11%) | catalogued as rs1337099154; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826499 C>A | 3'Flank (SNP) | VAF 24/694 reads (3%) | called by muse, mutect2
- AMPD1 | c.1779-39C>A | Intron (SNP) | VAF 60/271 reads (22%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501861 A>G | 5'Flank (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- APCDD1L | c.49+835G>T | Intron (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- BCAR1 | c.634-753G>C | Intron (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- BICD1 | c.2570+28G>T | Intron (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+39684C>A | Intron (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- C19orf12 | chr19:29701938 G>A | 3'Flank (SNP) | VAF 14/358 reads (4%) | called by muse, mutect2
- C1orf220 | n.466G>C | RNA (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- C4orf50 | c.-1279T>A | 5'UTR (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- C6orf201 | c.285-6367T>A | Intron (SNP) | VAF 19/213 reads (9%) | called by muse, mutect2
- CATIP | c.756-13T>C | Intron (SNP) | VAF 28/315 reads (9%) | catalogued as rs775616561; called by muse, mutect2
- CCDC174 | c.-23G>T | 5'UTR (SNP) | VAF 28/171 reads (16%) | catalogued as rs745599337; called by muse, mutect2, varscan2
- CCDC39 | n.646G>T | RNA (SNP) | VAF 10/155 reads (6%) | called by muse, mutect2
- CDH4 | c.170-24485C>G | Intron (SNP) | VAF 15/223 reads (7%) | catalogued as COSV58325922; called by muse, mutect2
- CHRNA4 | c.*507T>C | 3'UTR (SNP) | VAF 5/35 reads (14%) | catalogued as rs1238479258; called by muse, mutect2, varscan2
- CLEC19A | c.*22C>A | 3'UTR (SNP) | VAF 17/254 reads (7%) | called by muse, mutect2
- CTNNA2 | c.1057-79566T>C | Intron (SNP) | VAF 14/152 reads (9%) | catalogued as rs770172244; called by muse, mutect2
- CUTA | c.42+63T>A | Intron (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- DCC | c.4255-172C>A | Intron (SNP) | VAF 12/134 reads (9%) | catalogued as rs1004407185; called by muse, mutect2
- DENND3 | c.2295+14A>T | Intron (SNP) | VAF 104/540 reads (19%) | called by mutect2, varscan2
- EEF2KMT | c.159+30G>A | Intron (SNP) | VAF 48/446 reads (11%) | called by muse, mutect2, varscan2
- EMD | c.449+21G>A | Intron (SNP) | VAF 28/449 reads (6%) | called by muse, mutect2
- FBLN1 | c.1698-9504C>T | Intron (SNP) | VAF 40/332 reads (12%) | called by muse, mutect2, varscan2
- FLJ40194 | n.130C>A | RNA (SNP) | VAF 27/249 reads (11%) | called by muse, mutect2, varscan2
- FMR1 | c.*866A>G | 3'UTR (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- HAND2 | c.*67G>T | 3'UTR (SNP) | VAF 17/198 reads (9%) | called by muse, mutect2
- HDAC6 | chrX:48801831 G>T | 5'Flank (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- HMCES | c.-9T>C | 5'UTR (SNP) | VAF 28/295 reads (9%) | called by muse, mutect2
- HSP90AA4P | n.1169G>A | RNA (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- IL10RA | c.*749G>T | 3'UTR (SNP) | VAF 17/359 reads (5%) | called by muse, mutect2
- KRT17 | c.835-27C>A | Intron (SNP) | VAF 38/294 reads (13%) | catalogued as rs1223509818; called by muse, mutect2, varscan2
- LINC01948 | n.378G>T | RNA (SNP) | VAF 19/289 reads (7%) | called by muse, mutect2
- LRP5L | n.757C>T | RNA (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+3128C>G | Intron (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- MBNL1 | c.175-18774A>G | Intron (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2
- MCM3 | c.222-486G>T | Intron (SNP) | VAF 53/302 reads (18%) | catalogued as COSV57718910; called by muse, mutect2, varscan2
- MFRP | chr11:119343895 C>A | 5'Flank (SNP) | VAF 26/453 reads (6%) | called by muse, mutect2
- MIR323A | n.49C>G | RNA (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- MOGAT3 | chr7:101203203 C>A | 5'Flank (SNP) | VAF 46/449 reads (10%) | catalogued as rs115696859; called by muse, mutect2
- MSL3P1 | n.1092A>T | RNA (SNP) | VAF 34/426 reads (8%) | catalogued as rs1427218097; called by muse, mutect2
- MTHFD1 | c.1885-42G>T | Intron (SNP) | VAF 12/288 reads (4%) | called by muse, mutect2
- MZT2B | c.319+1148G>T | Intron (SNP) | VAF 13/159 reads (8%) | called by muse, mutect2
- NBPF25P | n.2314G>T | RNA (SNP) | VAF 55/942 reads (6%) | catalogued as rs1194922225; called by muse, mutect2
- NCKAP1L | c.1479+14C>A | Intron (SNP) | VAF 27/264 reads (10%) | catalogued as COSV99515028; called by muse, mutect2, varscan2
- NDUFAF5 | c.*398A>G | 3'UTR (SNP) | VAF 24/185 reads (13%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-110029G>T | Intron (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- OCA2 | c.*42C>G | 3'UTR (SNP) | VAF 70/401 reads (17%) | catalogued as rs756692515; called by muse, mutect2, varscan2
- OFD1 | c.1056-635C>G | Intron (SNP) | VAF 18/430 reads (4%) | called by muse, mutect2
- OR3A4P | n.1045C>A | RNA (SNP) | VAF 17/159 reads (11%) | called by muse, mutect2, varscan2
- OR51F5P | n.602G>T | RNA (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- OR52A4P | n.684G>A | RNA (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- OR5E1P | n.548C>A | RNA (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.1237-608G>A | Intron (SNP) | VAF 15/85 reads (18%) | catalogued as rs1421428021; called by muse, mutect2, varscan2
- PPM1K | c.542-2161G>T | Intron (SNP) | VAF 44/265 reads (17%) | catalogued as COSV99901067; called by muse, mutect2, varscan2
- PRELID3A | c.-7G>T | 5'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs530646338; called by mutect2, varscan2
- QKI | c.1010-1226C>G | Intron (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- RGL2 | c.240+95_241-119del | Intron (DEL) | VAF 28/162 reads (17%) | called by mutect2, pindel
- RNU6-389P | chr7:55685265 del G | 5'Flank (DEL) | VAF 36/371 reads (10%) | called by mutect2, pindel
- SEPTIN9 | c.722-6586G>T | Intron (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- SLC6A17 | c.1492+12C>A | Intron (SNP) | VAF 69/308 reads (22%) | catalogued as rs1234827340, COSV100521565; called by muse, mutect2, varscan2
- SPN | chr16:29670803 T>C | 3'Flank (SNP) | VAF 11/155 reads (7%) | called by muse, mutect2
- SPTA1 | c.6789-36T>A | Intron (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- SRRM2-AS1 | n.511A>G | RNA (SNP) | VAF 24/226 reads (11%) | catalogued as rs1365870094; called by muse, mutect2
- STAG3L4 | n.403G>T | RNA (SNP) | VAF 38/279 reads (14%) | called by muse, mutect2, varscan2
- SVIL2P | n.1375G>T | RNA (SNP) | VAF 15/242 reads (6%) | called by muse, mutect2
- SYNPO2L | c.*1673C>A | 3'UTR (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- TMCO1 | c.*3559C>G | 3'UTR (SNP) | VAF 11/300 reads (4%) | called by muse, mutect2
- TMEM245 | c.2123+3998A>G | Intron (SNP) | VAF 7/56 reads (13%) | catalogued as rs373868212; called by mutect2, varscan2
- TSC2 | c.3814+26C>T | Intron (SNP) | VAF 53/282 reads (19%) | catalogued as rs374901583; called by muse, mutect2, varscan2
- TSHR | c.692+100A>G | Intron (SNP) | VAF 22/165 reads (13%) | called by muse, mutect2, varscan2
- TTC3P1 | n.4498G>T | RNA (SNP) | VAF 15/151 reads (10%) | catalogued as rs1229690353; called by muse, mutect2
- TUBB7P | n.811G>T | RNA (SNP) | VAF 4/128 reads (3%) | called by muse, mutect2
- UBE2DNL | n.407C>T | RNA (SNP) | VAF 11/247 reads (4%) | catalogued as rs1274228322; called by muse, mutect2
- UQCRB | c.*2205G>T | 3'UTR (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- VSX1 | chr20:25071220 G>T | 3'Flank (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- ZNF521 | c.41-75G>A | Intron (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2, varscan2
- ZNF534 | c.-37G>T | 5'UTR (SNP) | VAF 15/226 reads (7%) | called by muse, mutect2
